Somatic mutation profile of tumor specimen TCGA-HC-8257-01A (aliquot TCGA-HC-8257-01A-11D-2260-08) from TCGA case TCGA-HC-8257, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.2 years (25,629 days).
Specimen TCGA-HC-8257-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f048d9e5-0b18-4f16-8d72-eb6851ccac28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8257-10A (Blood Derived Normal), aliquot TCGA-HC-8257-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54c1892a-6734-45da-bf2e-aa5aa2c0cefe

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 28, Silent 14, Frame Shift Del 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP8 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.938); catalogued as rs773404765, COSV54103160; called by muse, mutect2, varscan2
- C16orf70 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54627782; called by muse, mutect2
- CCDC66 | c.1886G>A p.C629Y (on ENST00000394672 / NM_001353147.1; = p.C595Y on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1243575432, COSV58305283; called by muse, mutect2, varscan2
- CCNF | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1199575804, COSV53540847; called by muse, mutect2, varscan2
- CMYA5 | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1207371594, COSV71406772; called by muse, mutect2, varscan2
- DNHD1 | c.13433G>A p.R4478Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV54437977; called by muse, mutect2, varscan2
- DUS2 | c.642C>T p.N214= | Splice Region (SNP) | VAF 23/75 reads (31%) | catalogued as rs563502920, COSV62708913; called by muse, mutect2, varscan2
- EPX | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56597028; called by muse, mutect2, varscan2
- FKTN | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs139291792, COSV56310265; called by muse, mutect2, varscan2
- HOGA1 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM154490, COSV53968558, COSV53969355; called by muse, mutect2
- IFI16 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV55535501; called by muse, mutect2, varscan2
- KCNRG | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57249041; called by muse, mutect2, varscan2
- MLC1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs568289086, COSV61117647; called by muse, mutect2, varscan2
- MTBP | c.1805A>T p.D602V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59963739; called by muse, mutect2, varscan2
- MTERF2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV53527851; called by muse, mutect2, varscan2
- NRP2 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 161/514 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313539710, COSV55930324; called by muse, mutect2, varscan2
- RING1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV63002660; called by muse, mutect2
- SNAI3 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139790709; called by muse, mutect2
- ST8SIA4 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | PolyPhen benign (0.125); catalogued as COSV51511851; called by muse, mutect2, varscan2
- STAC2 | c.1046T>A p.V349E | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100336261, COSV61065819; called by muse, mutect2
- TG | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs770118724, COSV55081121; called by muse, mutect2, varscan2
- TMEM102 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV53440164; called by muse, mutect2, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- USP9X | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV61070917; called by muse, mutect2, varscan2
- VCAN | c.9562C>T p.R3188C | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768294015, COSV54108143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF219 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV53881236; called by muse, mutect2, varscan2
- ZNF385D | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs370927931; called by muse, mutect2, varscan2
- ZNF407 | c.708A>T p.Q236H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55257584; called by muse, mutect2, varscan2
- CHRNB2 | c.139del p.R47Afs*10 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- IGHG4 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4C46 | c.138del p.I47Sfs*33 | Frame Shift Del (DEL) | VAF 64/261 reads (25%) | called by mutect2, pindel, varscan2
- TRPM4 | c.3351del p.E1118Sfs*5 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- ATG13 | c.1278C>T p.S426= (on ENST00000359513 / NM_001346321.1; = p.S389= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1397989340, COSV56320176; called by muse, mutect2
- C16orf70 | c.189C>T p.D63= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs376996983; called by muse, mutect2
- FAM13A | c.1848C>G p.L616= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs780288562, COSV52005099; called by muse, mutect2, varscan2
- FUT2 | c.873C>T p.F291= | Silent (SNP) | VAF 31/267 reads (12%) | catalogued as rs749093720, COSV67179439; called by muse, mutect2, varscan2
- GNL1 | c.829C>A p.R277= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV64835304; called by muse, mutect2
- ITGAE | c.2271C>T p.S757= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs551577998, COSV53995670; called by muse, mutect2, varscan2
- KIF16B | c.1461G>A p.T487= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV61707777; called by muse, mutect2
- MRGPRX2 | c.144C>T p.N48= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs750169111, COSV61674361; called by muse, mutect2, varscan2
- PSG6 | c.1047C>T p.L349= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as rs768478328, COSV51831110, COSV51835705; called by muse, mutect2, varscan2
- PTPRC | c.3153C>T p.F1051= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV61414154; called by muse, mutect2, varscan2
- SEPTIN6 | c.609C>T p.S203= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs143380835, COSV59715037; called by muse, mutect2, varscan2
- SH3BP5L | c.138C>A p.A46= | Silent (SNP) | VAF 76/235 reads (32%) | catalogued as COSV63539451; called by muse, mutect2, varscan2
- SHOC1 | c.2520G>T p.V840= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV59503304; called by muse, mutect2, varscan2
- VWA8 | c.4203C>T p.F1401= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV64997550; called by muse, mutect2, varscan2
